Somatic mutation profile of tumor specimen ALCH-ADRK-TTP1-A (aliquot ALCH-ADRK-TTP1-A-6-0-D-A532-36) from ALCHEMIST case ALCH-ADRK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.6 years (23,246 days).
Specimen ALCH-ADRK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6aa556c-8ea5-4b41-8ff2-dfedea01aca2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADRK-NB1-A (Blood Derived Normal), aliquot ALCH-ADRK-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0079f68d-ff29-4f43-8bd8-d6615b770504

The open-access MAF lists 263 somatic variants for this specimen: 165 protein-altering or splice-affecting, 53 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 53, Intron 21, Nonsense Mutation 19, RNA 9, 5'UTR 8, Splice Site 4, 3'UTR 4, 3'Flank 2, In Frame Del 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2254_2277del p.S752_I759del | In Frame Del (DEL) | VAF 1380/2281 reads (60%) | hotspot (GDC flag); catalogued as rs121913463, COSV51774879; ClinVar: drug response; called by mutect2, pindel, varscan2
- ABCD1 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 48/303 reads (16%) | catalogued as CM021058; called by muse, mutect2, varscan2
- ADAM15 | c.1808T>C p.I603T | Missense Mutation (SNP) | VAF 56/767 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs776120235; called by muse, mutect2
- ADCY2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV100602145, COSV100603543; called by muse, mutect2
- AIM2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 26/591 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs1303027808; called by muse, mutect2
- ANKRD9 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54601761; called by muse, mutect2
- ARG2 | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.305); catalogued as COSV55775646; called by muse, mutect2
- ARHGAP15 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753972109; called by muse, mutect2, varscan2
- C16orf70 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV54628508; called by muse, mutect2
- C19orf33 | c.286_288del p.K96del | In Frame Del (DEL) | VAF 36/309 reads (12%) | catalogued as rs752832965; called by pindel, varscan2
- CACNA1I | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.33); catalogued as rs746228837, COSV60801784; called by muse, mutect2, varscan2
- CACNA2D3 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55564226; called by muse, mutect2
- CLTC | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 27/482 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as COSV52247564; called by muse, mutect2
- COL11A2 | c.4808G>A p.C1603Y (on ENST00000341947 / NM_080680.3; = p.C1496Y on NM_080679.2) | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1191829072; called by muse, mutect2
- DGKK | c.1811G>C p.R604T | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV65709377; called by muse, mutect2
- DNAH10 | c.1231-1G>A p.X411_splice (on ENST00000409039; = p.X350_splice on NM_207437.3) | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as COSV68987332; called by muse, mutect2
- DQX1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66353733; called by muse, mutect2
- EPS8L2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs761405492; called by mutect2, varscan2
- ETNPPL | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV56594370; called by muse, mutect2
- ETV2 | c.422C>G p.S141W | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1435567426, COSV55837536, COSV55838312; called by muse, mutect2
- FBXO38 | c.2532G>C p.E844D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs777947285; called by mutect2, varscan2
- FOXP1 | c.1732G>T p.A578S | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV100561789; called by muse, mutect2
- GABRR1 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 33/1017 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV65620155, COSV65620270; called by muse, mutect2
- HIVEP3 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143274774, COSV56016266; called by muse, mutect2, varscan2
- IGSF3 | c.3370G>A p.A1124T (on ENST00000369486 / NM_001007237.3; = p.A1144T on NM_001542.4) | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs368581214; called by muse, mutect2, varscan2
- ITGAX | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs1312125550; called by muse, mutect2, varscan2
- KCNA6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54974128, COSV99768741; called by muse, mutect2, varscan2
- LARP1 | c.2140A>G p.M714V (on ENST00000518297 / NM_033551.3; = p.M637V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1233210446; called by muse, mutect2
- MAGEA11 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 20/427 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs868960320, COSV60758687; called by muse, mutect2
- MAJIN | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs971680012; called by muse, mutect2, varscan2
- MAP1A | c.3416G>C p.R1139T | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); catalogued as rs750541025, COSV55805547; called by muse, mutect2
- MAST2 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100788452; called by muse, mutect2, varscan2
- MCRS1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs1159458580; called by muse, mutect2, varscan2
- MEAK7 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | catalogued as rs1325308492; called by muse, mutect2
- METTL1 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 37/189 reads (20%) | catalogued as rs767185401; called by muse, mutect2, varscan2
- MLF2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); catalogued as rs972380193; called by muse, mutect2, varscan2
- MSTO1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV55472236; called by muse, mutect2
- NPAS3 | c.2164G>A p.D722N (on ENST00000356141 / NM_001164749.2; = p.D690N on NM_022123.3) | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60834783; called by muse, mutect2
- NTM | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779050882, COSV66178975; called by muse, mutect2
- NUCKS1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV65652941; called by muse, mutect2
- OAS3 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1018742530; called by muse, mutect2, varscan2
- PCDHB16 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 21/515 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53358709, COSV99502359; called by muse, mutect2
- PGBD5 | c.895G>A p.A299T (on ENST00000525115; = p.A368T on NM_001258311.2) | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs371374137; called by muse, mutect2, varscan2
- PTGIS | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs139949009; called by muse, mutect2, varscan2
- RAB36 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532442393; called by muse, mutect2, varscan2
- RB1 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs483352690, CM034902, CM045967, CS050405, CS081965, CS083261, COSV57303318, COSV57309017, COSV57322012; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RGL3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs749905799; called by muse, mutect2, varscan2
- SENP7 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs1250960720; called by muse, mutect2
- SETX | c.6331G>C p.E2111Q | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.833); catalogued as COSV104385569; called by muse, mutect2
- SLC24A2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 24/587 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV53865168; called by muse, mutect2
- SLC26A5 | c.1987-1G>A p.X663_splice | Splice Site (SNP) | VAF 10/164 reads (6%) | catalogued as COSV59703874; called by muse, mutect2
- SYMPK | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 22/172 reads (13%) | catalogued as COSV55609795; called by muse, mutect2, varscan2
- TEX55 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs758956113, COSV55210774; called by muse, mutect2, varscan2
- THSD7B | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 30/214 reads (14%) | catalogued as COSV99759368; called by muse, mutect2, varscan2
- TNXB | c.7393G>A p.E2465K (on ENST00000647633; = p.E2218K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as rs530280191, COSV64480788; called by muse, mutect2
- TP53I13 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291425143, COSV56402489, COSV56403221; called by muse, mutect2
- TRBV29-1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 40/593 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1265856260; called by muse, mutect2
- TRIM28 | c.1250C>G p.S417* | Nonsense Mutation (SNP) | VAF 14/298 reads (5%) | catalogued as COSV99449096; called by muse, mutect2
- TSNAXIP1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 11/152 reads (7%) | catalogued as COSV99535001; called by muse, mutect2
- TTC26 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 56/528 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373757821; called by muse, mutect2, varscan2
- TTR | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 62/796 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371566010, CM035093, COSV52701509; called by muse, mutect2
- VGLL1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1376789549; called by muse, mutect2
- VSX1 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1249254343; called by muse, mutect2
- WNT11 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.357); catalogued as rs1046121955, COSV59443551; called by muse, mutect2
- XYLT1 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759525034; called by muse, mutect2, varscan2
- ZCCHC9 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54176257; called by muse, mutect2
- ZNF229 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 43/203 reads (21%) | catalogued as COSV99351030; called by muse, mutect2, varscan2
- ZNF502 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.11); catalogued as COSV99939854; called by muse, mutect2, varscan2
- ZNF559 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 15/168 reads (9%) | catalogued as COSV100416665; called by muse, mutect2
- ACP3 | c.552T>A p.Y184* | Nonsense Mutation (SNP) | VAF 67/141 reads (48%) | called by muse, mutect2, varscan2
- ARID2 | c.2149A>G p.T717A | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARSD | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AVL9 | c.1817C>A p.T606K | Missense Mutation (SNP) | VAF 160/404 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- B4GALNT4 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BARX1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, varscan2
- BPNT2 | c.1015A>T p.I339F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); called by muse, mutect2
- CALCOCO1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CCDC120 | c.1865C>G p.S622C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CEP170B | c.4327C>T p.Q1443* (on ENST00000453495; = p.Q1372* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
- CIC | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CIC | c.4020G>C p.K1340N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CPXM1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.10396C>G p.L3466V | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.566); called by muse, mutect2
- DAAM1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 174/678 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- DCAF12L1 | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.037); called by muse, mutect2
- DDX46 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2
- DNASE1L2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DOCK2 | c.5047C>A p.P1683T | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- DYNC1H1 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.338); called by muse, mutect2
- E4F1 | c.2159C>T p.T720I | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EFCAB5 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.164); called by muse, mutect2
- ELF4 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ENC1 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- EPHB2 | c.1935G>C p.K645N (on ENST00000400191 / NM_001309193.2; = p.K646N on NM_004442.7) | Missense Mutation (SNP) | VAF 29/437 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- EPOR | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ERVV-2 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 148/301 reads (49%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GABRA1 | c.1103dup p.Y368* | Nonsense Mutation (INS) | VAF 24/228 reads (11%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- GDF10 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GLG1 | c.68T>G p.F23C | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GOLGA6L2 | c.223A>T p.N75Y | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIA2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2
- GRM8 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- HSPA2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 36/655 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- INTS2 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- JAG1 | c.1644C>G p.F548L | Missense Mutation (SNP) | VAF 65/1045 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- JOSD2 | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- JTB | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
- KBTBD2 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNA2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 33/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL24 | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KLK13 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KRTAP29-1 | c.798C>G p.N266K | Missense Mutation (SNP) | VAF 28/664 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2
- KRTAP29-1 | c.264C>G p.H88Q | Missense Mutation (SNP) | VAF 19/471 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- LY75 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAP3K4 | c.718A>T p.K240* | Nonsense Mutation (SNP) | VAF 44/378 reads (12%) | called by muse, varscan2
- MAS1 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- MCM7 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MED1 | c.2653G>C p.E885Q | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); called by muse, mutect2
- MRC1 | c.4120G>T p.A1374S | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.322); called by muse, mutect2
- MRM3 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 49/326 reads (15%) | called by muse, mutect2, varscan2
- MXD1 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- MYSM1 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOC3L | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.082); called by muse, mutect2
- NT5E | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 40/560 reads (7%) | called by muse, mutect2
- OFD1 | c.2944G>A p.V982I | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2
- ORAI1 | c.34A>C p.S12R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- OSBPL3 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2
- P2RY10 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2289C>G p.F763L | Missense Mutation (SNP) | VAF 18/413 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.144); called by muse, mutect2
- PCDHGA12 | c.1683G>C p.E561D | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); called by muse, mutect2
- PDE1C | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2
- PHF3 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2
- PHYKPL | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 27/376 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2
- PLEKHA2 | c.1068del p.W357Gfs*41 | Frame Shift Del (DEL) | VAF 77/338 reads (23%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PRDM1 | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 42/636 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2
- PRKD1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 47/1120 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- PTGES3L-AARSD1 | c.861G>C p.Q287H (on ENST00000421990 / NM_001136042.2; = p.Q269H on NM_025267.3) | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PTPN11 | c.1713-1G>C p.X571_splice | Splice Site (SNP) | VAF 31/360 reads (9%) | called by muse, mutect2
- PTPN12 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RDH12 | c.368T>A p.I123N | Missense Mutation (SNP) | VAF 22/612 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REV3L | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPO1 | c.41G>C p.W14S | Missense Mutation (SNP) | VAF 97/419 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL4 | c.2849C>G p.S950* | Nonsense Mutation (SNP) | VAF 46/680 reads (7%) | called by muse, mutect2
- SAXO2 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 61/392 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SETBP1 | c.445A>G p.K149E | Missense Mutation (SNP) | VAF 45/571 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2
- SLC25A14 | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- SLC36A1 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.055); called by muse, mutect2
- SMARCA1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SSX2IP | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 16/459 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.288); called by muse, mutect2
- TCF20 | c.2499G>T p.Q833H | Missense Mutation (SNP) | VAF 22/445 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- TKT | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TLK2 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2
- TMEM53 | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 127/483 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP3B | c.72G>A p.G24= | Splice Region (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- TPH1 | c.1158G>C p.M386I | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); called by muse, mutect2
- TUT1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- UBR3 | c.5596G>C p.E1866Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UBR4 | c.9853C>T p.Q3285* | Nonsense Mutation (SNP) | VAF 46/516 reads (9%) | called by muse, mutect2
- WDPCP | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.32); called by muse, mutect2
- XKR3 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ZFAND2B | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ZNF200 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF699 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- ACSBG1 | c.1884G>A p.L628= | Silent (SNP) | VAF 13/266 reads (5%) | catalogued as rs1377194386; called by muse, mutect2
- ACTRT1 | c.825C>T p.L275= | Silent (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- ADAM20 | c.1962C>T p.C654= | Silent (SNP) | VAF 113/494 reads (23%) | called by muse, mutect2, varscan2
- ATP13A2 | c.1491C>T p.H497= | Silent (SNP) | VAF 68/311 reads (22%) | catalogued as COSV58702414; called by muse, mutect2, varscan2
- CA12 | c.639G>A p.E213= | Silent (SNP) | VAF 22/553 reads (4%) | called by muse, mutect2
- CCDC85C | c.894G>T p.T298= | Silent (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- CDH1 | c.2373C>G p.L791= | Silent (SNP) | VAF 53/288 reads (18%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.39C>T p.L13= | Silent (SNP) | VAF 40/179 reads (22%) | called by muse, mutect2, varscan2
- CSMD2 | c.5427C>G p.S1809= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as COSV53890486; called by muse, mutect2, varscan2
- DIAPH2 | c.3165G>C p.V1055= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- FAM120AOS | c.618G>A p.L206= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs376076312; called by muse, mutect2, varscan2
- FBXO33 | c.975C>T p.V325= | Silent (SNP) | VAF 44/422 reads (10%) | called by muse, mutect2, varscan2
- FRMD6 | c.27C>T p.N9= | Silent (SNP) | VAF 22/554 reads (4%) | called by muse, mutect2
- GFI1 | c.1233C>T p.L411= | Silent (SNP) | VAF 16/466 reads (3%) | called by muse, mutect2
- H1-10 | c.240C>T p.F80= | Silent (SNP) | VAF 39/393 reads (10%) | catalogued as rs775270271; called by muse, mutect2, varscan2
- IGFN1 | c.2112C>T p.F704= (on ENST00000295591 / NM_001367841.1; = p.F3161= on NM_001164586.2) | Silent (SNP) | VAF 13/276 reads (5%) | called by muse, mutect2
- JPH3 | c.1791C>T p.G597= | Silent (SNP) | VAF 28/394 reads (7%) | catalogued as rs767240603; called by muse, mutect2
- KATNA1 | c.237C>T p.D79= | Silent (SNP) | VAF 27/242 reads (11%) | called by muse, mutect2
- KIAA1755 | c.1911C>T p.D637= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as rs112826952; called by muse, mutect2, varscan2
- LAMB2 | c.2142C>G p.L714= | Silent (SNP) | VAF 25/376 reads (7%) | called by muse, mutect2
- LMTK3 | c.3939C>G p.V1313= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99540384; called by muse, mutect2
- MAP3K4 | c.789G>A p.L263= | Silent (SNP) | VAF 58/274 reads (21%) | catalogued as rs1212928303; called by muse, varscan2
- MAPK8IP3 | c.357G>A p.K119= | Silent (SNP) | VAF 23/210 reads (11%) | called by muse, mutect2, varscan2
- MCTP2 | c.1125G>A p.E375= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- MXD1 | c.63G>A p.R21= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MYO1E | c.1854G>C p.V618= | Silent (SNP) | VAF 83/428 reads (19%) | called by muse, mutect2, varscan2
- NACAD | c.4638G>C p.L1546= | Silent (SNP) | VAF 20/518 reads (4%) | called by muse, mutect2
- NAV2 | c.2073C>T p.N691= (on ENST00000396087 / NM_001244963.2; = p.N668= on NM_145117.5) | Silent (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- NOTCH4 | c.1062G>A p.E354= | Silent (SNP) | VAF 42/656 reads (6%) | called by muse, mutect2
- OR10C1 | c.243G>T p.L81= (on ENST00000622521; = p.L79= on NM_013941.3) | Silent (SNP) | VAF 20/203 reads (10%) | catalogued as COSV65824168; called by muse, mutect2, varscan2
- OR4X1 | c.651G>T p.L217= | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- OR51I1 | c.135C>G p.L45= | Silent (SNP) | VAF 28/504 reads (6%) | called by muse, mutect2
- OR9G4 | c.198G>A p.L66= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV57249367; called by muse, mutect2, varscan2
- PAFAH1B3 | c.132C>T p.I44= | Silent (SNP) | VAF 20/308 reads (6%) | catalogued as rs1439704851; called by muse, mutect2
- PCDHB10 | c.909C>T p.L303= | Silent (SNP) | VAF 20/314 reads (6%) | catalogued as COSV53375016; called by muse, mutect2
- RNASEH2A | c.48G>A p.L16= | Silent (SNP) | VAF 21/282 reads (7%) | called by muse, mutect2
- RPTN | c.27C>A p.L9= | Silent (SNP) | VAF 14/293 reads (5%) | called by muse, mutect2
- RYR1 | c.6180C>T p.G2060= | Silent (SNP) | VAF 45/619 reads (7%) | called by muse, mutect2
- SCML4 | c.24G>A p.G8= | Silent (SNP) | VAF 21/193 reads (11%) | called by muse, mutect2, varscan2
- SERGEF | c.1197C>G p.L399= | Silent (SNP) | VAF 19/222 reads (9%) | called by muse, mutect2
- SLCO5A1 | c.258G>A p.P86= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs777138818, COSV52657734; called by muse, mutect2, varscan2
- SP4 | c.51G>A p.A17= | Silent (SNP) | VAF 52/591 reads (9%) | called by muse, mutect2
- SUN5 | c.141C>T p.D47= | Silent (SNP) | VAF 78/512 reads (15%) | catalogued as rs375807222; called by muse, mutect2, varscan2
- TAF7 | c.498G>C p.V166= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- TCERG1L | c.1371C>T p.F457= | Silent (SNP) | VAF 33/461 reads (7%) | called by muse, mutect2
- TMEM115 | c.846G>C p.R282= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- TRIM56 | c.1677G>A p.Q559= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- UHRF2 | c.1081C>T p.L361= | Silent (SNP) | VAF 26/382 reads (7%) | catalogued as rs1244093706; called by muse, mutect2
- VCAN | c.405G>A p.G135= | Silent (SNP) | VAF 60/402 reads (15%) | catalogued as rs371005267; called by muse, mutect2, varscan2
- VPS11 | c.489C>T p.S163= (on ENST00000620429; = p.S707= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 60/483 reads (12%) | catalogued as rs782272810, COSV100333567; called by muse, mutect2, varscan2
- WDR24 | c.411G>A p.L137= (on ENST00000248142; = p.L75= on NM_032259.4) | Silent (SNP) | VAF 35/403 reads (9%) | catalogued as COSV50196356; called by muse, mutect2
- ZIC2 | c.1029C>G p.V343= | Silent (SNP) | VAF 20/291 reads (7%) | catalogued as CD011669; called by muse, mutect2
- ZSCAN20 | c.1494C>G p.L498= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- AC009093.9 | n.1171C>T | RNA (SNP) | VAF 44/458 reads (10%) | catalogued as rs1471768370; called by muse, mutect2, varscan2
- AC022748.1 | n.253G>A | RNA (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- ADAMTS2 | c.1629+952G>A | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- ALMS1P1 | n.1043-9722C>T | Intron (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.481-16C>A | Intron (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- BUD23 | c.702-160G>C | Intron (SNP) | VAF 10/210 reads (5%) | catalogued as rs1212162592; called by muse, mutect2
- C7orf66 | n.260C>G | RNA (SNP) | VAF 19/537 reads (4%) | called by muse, mutect2
- CAST | c.-4C>T | 5'UTR (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- CCDC12 | c.244+204C>T | Intron (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- CENPM | c.231-78G>C | Intron (SNP) | VAF 16/117 reads (14%) | catalogued as COSV53245166; called by muse, mutect2
- CLASP1 | c.196-624C>G | Intron (SNP) | VAF 94/466 reads (20%) | catalogued as rs769219094; called by muse, mutect2, varscan2
- CYLD | chr16:50806782 del TC | 3'Flank (DEL) | VAF 37/222 reads (17%) | called by mutect2, pindel, varscan2
- DNAJC19 | c.*75C>G | 3'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs1200548043; called by muse, mutect2
- DPH1 | c.62-100G>C | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- EARS2 | c.296-1729G>C | Intron (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
- FANCA | c.80-20G>C | Intron (SNP) | VAF 50/784 reads (6%) | called by muse, mutect2
- FGFR3 | chr4:1807627 C>G | 3'Flank (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- GCDH | c.-8G>A | 5'UTR (SNP) | VAF 20/227 reads (9%) | called by muse, mutect2
- GLB1L3 | c.812-15C>T | Intron (SNP) | VAF 26/456 reads (6%) | called by muse, mutect2
- GRAP2 | c.-69C>G | 5'UTR (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- HMGB1P1 | n.346G>C | RNA (SNP) | VAF 20/420 reads (5%) | called by muse, mutect2
- HSD17B10 | c.27+75G>C | Intron (SNP) | VAF 49/249 reads (20%) | called by muse, mutect2, varscan2
- LINC02870 | n.314C>T | RNA (SNP) | VAF 126/338 reads (37%) | called by muse, mutect2, varscan2
- LRRC14 | c.*2818G>C | 3'UTR (SNP) | VAF 31/657 reads (5%) | called by muse, mutect2
- LUC7L | c.61+350C>T | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- MAD2L2 | c.427+23C>G | Intron (SNP) | VAF 17/345 reads (5%) | called by muse, mutect2
- MYH16 | n.4613G>T | RNA (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- MYO5B | c.4222-35G>A | Intron (SNP) | VAF 49/434 reads (11%) | called by muse, mutect2
- MYO5C | c.449+926G>A | Intron (SNP) | VAF 28/324 reads (9%) | called by muse, mutect2
- NBPF11 | c.-549+2421G>A | Intron (SNP) | VAF 50/726 reads (7%) | catalogued as rs1267798121; called by muse, mutect2
- OBSCN | c.18662-1979C>T | Intron (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- PRSS30P | n.2767G>A | RNA (SNP) | VAF 42/195 reads (22%) | called by muse, mutect2, varscan2
- RNF170 | c.-88G>A | 5'UTR (SNP) | VAF 64/580 reads (11%) | catalogued as rs1330584519; called by muse, mutect2
- SAV1 | c.*970G>A | 3'UTR (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- SLC26A9 | c.*299C>T | 3'UTR (SNP) | VAF 32/363 reads (9%) | called by muse, mutect2
- SNX3 | c.258+684C>G | Intron (SNP) | VAF 19/300 reads (6%) | called by muse, mutect2
- SPATA31C1 | n.3380C>G | RNA (SNP) | VAF 46/457 reads (10%) | called by muse, mutect2, varscan2
- SRPX2 | c.-33C>G | 5'UTR (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- SYNE2 | c.18038+761G>A | Intron (SNP) | VAF 81/1046 reads (8%) | called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 16/170 reads (9%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
- TMCO6 | c.-24C>T | 5'UTR (SNP) | VAF 18/320 reads (6%) | catalogued as rs1422466228; called by muse, mutect2
- ZNF207 | c.41+24G>C | Intron (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- ZNF322P1 | n.160G>A | RNA (SNP) | VAF 36/399 reads (9%) | called by muse, mutect2
- ZNF391 | c.-324T>G | 5'UTR (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- ZNF467 | chr7:149776430 C>T | 5'Flank (SNP) | VAF 30/354 reads (8%) | catalogued as rs111404189; called by muse, mutect2
